Gene-level copy-number profile of tumor specimen TCGA-IF-A4AJ-01A from TCGA case TCGA-IF-A4AJ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 80.7 years (29,469 days).
Specimen TCGA-IF-A4AJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.60f924df-f5b8-4b65-ac22-3c1289e8f6f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IF-A4AJ-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/41a57aa0-a746-45e7-9929-1de96d41844b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,243; copy number 2: 22,357; copy number 3: 19,122; copy number 4: 15,396; copy number 5: 297; copy number 6: 398.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IF-A4AJ-01A-11D-A24M-01): tumor purity 0.7, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:203,313–206,392, 1 gene: AL035696.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 695 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:36,764,445–43,674,591, 177 genes, copy number 5 (broad region; genes not listed).
- chr8:64,331,927–70,535,646, 104 genes, copy number 5 (broad region; genes not listed).
- chr18:25,016,434–26,391,685, 16 genes, copy number 5 (within-gene range 2–5): WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1.
- chr20:4,590,993–26,251,546, 398 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,243. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
